Somatic mutation profile of tumor specimen TCGA-24-1430-01A (aliquot TCGA-24-1430-01A-01W-0545-08) from TCGA case TCGA-24-1430, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.3 years (24,939 days).
Specimen TCGA-24-1430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0e4d9f2-4ca0-4607-a32b-8f9cc5ab605f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1430-10A (Blood Derived Normal), aliquot TCGA-24-1430-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1502039e-1c7b-47d6-a715-9234333c357b

The open-access MAF lists 82 somatic variants for this specimen: 69 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 12, Frame Shift Ins 3, Splice Region 1, 3'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX2 | c.90dup p.S31Lfs*130 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 145/165 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.797A>G p.Q266R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV100185201; called by muse, mutect2, varscan2
- ASXL3 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99324027, COSV99326364; called by muse, mutect2, varscan2
- BAZ2B | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 215/667 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100600494; called by muse, mutect2, varscan2
- BFAR | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 290/314 reads (92%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as COSV99902110; called by muse, varscan2
- BFSP1 | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 75/135 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484446153, COSV100925336; called by muse, mutect2, varscan2
- C3AR1 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV99368265; called by muse, mutect2, varscan2
- CDH9 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535692550, COSV50266744; called by muse, mutect2, varscan2
- CHST14 | c.1033dup p.R345Pfs*10 | Frame Shift Ins (INS) | VAF 7/68 reads (10%) | catalogued as rs774738190; called by mutect2, pindel
- CIART | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 649/1394 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782449723, COSV51745318; called by muse, varscan2
- COL5A2 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100880103, COSV66414438; called by muse, mutect2
- CRTAM | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as rs143016653; called by muse, varscan2
- DBR1 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99604420; called by muse, mutect2
- DHX16 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs768315559, COSV100906060; called by muse, mutect2, varscan2
- DNAJB11 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV99408572; called by muse, mutect2, varscan2
- EYA2 | c.355T>A p.Y119N | Missense Mutation (SNP) | VAF 26/976 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100426610; called by muse, mutect2
- F5 | c.3467T>C p.M1156T | Missense Mutation (SNP) | VAF 87/1510 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as rs150779589; called by muse, mutect2
- FLAD1 | c.1177C>G p.Q393E | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV52700032; called by muse, mutect2
- H2AC6 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 93/101 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV100019819; called by muse, mutect2, varscan2
- H3C13 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1265041360; called by muse, mutect2
- HHIP | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 94/104 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV56844434; called by muse, mutect2, varscan2
- IGF2R | c.6953C>G p.T2318S | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1404361029; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 373/410 reads (91%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.513); catalogued as rs761757270; called by muse, mutect2, varscan2
- KIF3B | c.1714A>T p.T572S | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV100996350; called by muse, mutect2, varscan2
- KLHL5 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 117/269 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99785020; called by muse, mutect2, varscan2
- KRTAP20-2 | c.194A>C p.Y65S | Missense Mutation (SNP) | VAF 19/310 reads (6%) | PolyPhen probably damaging (0.923); catalogued as COSV100424463; called by muse, mutect2
- NMUR1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100531859; called by muse, mutect2, varscan2
- NWD1 | c.4400T>C p.L1467P (on ENST00000552788 / NM_001290355.3; = p.C1432R on NM_001007525.5) | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100342093; called by muse, mutect2
- OGFOD3 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100234345; called by muse, mutect2, varscan2
- OR1S2 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 175/444 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs768128612, COSV100224068; called by muse, mutect2, varscan2
- PADI4 | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100966726; called by muse, mutect2, varscan2
- PBX4 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV99232080; called by muse, mutect2
- PEX5 | c.1505G>A p.G502E (on ENST00000420616; = p.G494E on NM_000319.5) | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99870781; called by muse, mutect2, varscan2
- PFKP | c.1785dup p.L596Afs*6 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs747416036; called by mutect2, varscan2
- POGZ | c.2941G>C p.V981L | Missense Mutation (SNP) | VAF 81/505 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.056); catalogued as COSV99304885; called by muse, mutect2, varscan2
- QARS1 | c.1677T>G p.D559E | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.058); catalogued as COSV100069840; called by muse, mutect2
- RBAK-RBAKDN | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 307/346 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1309178908; called by muse, mutect2, varscan2
- RBBP8 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.071); catalogued as rs1379605556; called by muse, varscan2
- RIMS1 | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99325327; called by muse, mutect2
- SDK1 | c.448A>T p.S150C | Missense Mutation (SNP) | VAF 95/104 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV101268985; called by muse, mutect2, varscan2
- SLC6A1 | c.1315A>G p.I439V | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT tolerated (1); PolyPhen possibly damaging (0.765); catalogued as COSV99822567; called by muse, mutect2, varscan2
- SMC2 | c.1425G>C p.E475D | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV99658696; called by muse, mutect2, varscan2
- SPIRE1 | c.1927C>T p.P643S (on ENST00000409402 / NM_001128626.2; = p.P629S on NM_020148.3) | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.998); catalogued as rs1394931973, COSV100563479; called by muse, mutect2, varscan2
- TAF3 | c.1676T>G p.V559G | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100719963; called by muse, mutect2, varscan2
- TMC2 | c.2048A>G p.E683G | Missense Mutation (SNP) | VAF 379/607 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100727442, COSV62656463; called by muse, mutect2, varscan2
- TRIM48 | c.383G>C p.C128S | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101338238; called by muse, mutect2, varscan2
- TRIP6 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 102/170 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99307641; called by muse, mutect2, varscan2
- TSPOAP1 | c.3877G>C p.E1293Q | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV99270485; called by muse, mutect2
- TYW1 | c.797A>T p.H266L | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100658538; called by muse, mutect2, varscan2
- UNC13C | c.5311A>G p.K1771E | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); catalogued as COSV99514004; called by muse, mutect2, varscan2
- USP45 | c.1843T>C p.S615P | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV100569558; called by muse, mutect2, varscan2
- XIRP2 | c.5930T>C p.I1977T (on ENST00000628543; = p.I2152T on NM_152381.6) | Missense Mutation (SNP) | VAF 103/167 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99740503; called by muse, mutect2, varscan2
- ZNF282 | c.537C>A p.N179K | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100021523; called by muse, mutect2, varscan2
- ACAD9 | c.1468G>T p.V490L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ALPK3 | c.5044G>C p.E1682Q | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- CTSA | c.740A>C p.N247T | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ENPP6 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FSCB | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GDF15 | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- IFNAR2 | c.1101G>C p.E367D | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.43); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IL1RAP | c.63A>G p.S21= | Splice Region (SNP) | VAF 129/330 reads (39%) | called by muse, mutect2, varscan2
- LIPT1 | c.951T>G p.H317Q | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5C | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 60/63 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NR3C2 | c.2829C>G p.F943L | Missense Mutation (SNP) | VAF 104/121 reads (86%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PSAT1 | c.406del p.D136Ifs*58 | Frame Shift Del (DEL) | VAF 314/803 reads (39%) | called by mutect2, pindel, varscan2
- SYNE2 | c.2755A>G p.S919G | Missense Mutation (SNP) | VAF 148/298 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TENM3 | c.6086G>C p.S2029T | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2
- UNC79 | c.3043G>T p.V1015F (on ENST00000393151 / NM_001346218.2; = p.V838F on NM_020818.5) | Missense Mutation (SNP) | VAF 349/802 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ABCA9 | c.1932G>A p.P644= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs748167314; called by muse, mutect2, varscan2
- ARHGAP31 | c.3705A>G p.G1235= | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as COSV99956811; called by muse, mutect2, varscan2
- CELF2 | c.1526G>A p.*509= (on ENST00000416382 / NM_001025077.3; = p.*522= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 91/212 reads (43%) | catalogued as rs1442364182, COSV59974177; called by muse, mutect2, varscan2
- DNAH17 | c.6105G>A p.K2035= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV101101758; called by muse, varscan2
- H3C13 | c.60G>A p.Q20= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2
- HCK | c.1410G>A p.L470= | Silent (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- KIAA0586 | c.1386C>G p.T462= (on ENST00000619416 / NM_001244190.2; = p.T477= on NM_014749.5) | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- MMS22L | c.975A>G p.K325= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV99246367; called by muse, mutect2, varscan2
- P2RY12 | c.489C>A p.T163= | Silent (SNP) | VAF 105/217 reads (48%) | catalogued as COSV99852142; called by muse, mutect2, varscan2
- PAK5 | c.1305C>G p.A435= | Silent (SNP) | VAF 13/265 reads (5%) | called by muse, mutect2
- TRAV29DV5 | c.111G>C p.L37= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- ZMYND8 | c.1740C>A p.V580= (on ENST00000311275 / NM_001363741.2; = p.V600= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/260 reads (29%) | catalogued as COSV53697006; called by muse, mutect2, varscan2
- NPR3 | c.*3086C>A | 3'UTR (SNP) | VAF 275/694 reads (40%) | catalogued as COSV99422590; called by muse, mutect2, varscan2
